Gene-level copy-number profile of tumor specimen TCGA-C5-A1BF-01B from TCGA case TCGA-C5-A1BF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 46.5 years (16,975 days).
Specimen TCGA-C5-A1BF-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.fd7d0f9b-6ecf-46f1-9aa0-c4d7c69fc3d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1BF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ea8a09f-8b69-4eac-a7a4-3c64d8cd0c97

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 7,059; copy number 2: 47,327; copy number 3: 4,849; copy number 4: 373; copy number 5: 95; copy number 8: 95.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1BF-01B-11D-A13V-01): tumor purity 0.75, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,194,741–41,260,096, 1 gene (within-gene range 0–1): CTNNB1.
- chr11:85,336,075–86,278,813, 19 genes: AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:8,444,767–8,981,342, 18 genes, copy number 5 (within-gene range 3–5): HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16.
- chr19:10,416,773–11,835,216, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:22,298,124–22,329,122, 1 gene, copy number 8 (within-gene range 4–8): AC245060.7.
- chr22:22,318,727–22,923,034, 94 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,059. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
